Somatic mutation profile of tumor specimen 0DPMRP from CCDI case PBCCZB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Paraganglioma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 13.0 years (4,744 days).
Specimen 0DPMRP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4174ad2c-7faf-46ce-b756-9cb8f9d8fcf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/deb7cc6f-91cf-488a-885c-6f35b28e8821

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LPAR3 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.996); catalogued as rs544005031, COSV101004652; called by muse, mutect2, varscan2
- TMPRSS9 | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CTSD | c.*72C>T | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
